Gene-level copy-number profile of tumor specimen TCGA-13-0797-01A from TCGA case TCGA-13-0797, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.4 years (18,051 days).
Specimen TCGA-13-0797-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.14d6cfc7-8868-443e-8eaf-dc6c155958b0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0797-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6248fa9e-15bd-47cc-ad7f-a71740849e14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 16,085; copy number 2: 33,799; copy number 3: 7,744; copy number 4: 1,615; copy number 5: 177; copy number 6: 115; copy number 7: 81; copy number 10: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0797-01): tumor purity 0.89, ploidy 1.91, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:130,827,406–130,837,135, 1 gene: SMLR1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 461 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,037,252–26,229,840, 12 genes, copy number 6: SLC30A2, AL391650.2, TRIM63, PDIK1L, FAM110D, C1orf232, AL391650.1, ZNF593, CNKSR1, CATSPER4, ZPLD2P, AL355877.2.
- chr1:150,363,091–150,697,154, 16 genes, copy number 5 (within-gene range 3–5): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L.
- chr2:176,269,395–176,819,180, 9 genes, copy number 5 (within-gene range 3–5): MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P.
- chr2:186,354,570–187,003,377, 9 genes, copy number 5: AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7.
- chr8:128,150,116–128,564,679, 4 genes, copy number 5: MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:140,520,156–140,638,283, 4 genes, copy number 5 (within-gene range 4–5): AGO2, AC067931.1, AC067931.2, ERICD.
- chr8:140,732,564–140,732,653, 1 gene, copy number 5: MIR151A.
- chr8:143,541,648–145,066,685, 114 genes, copy number 5–6 (broad region; genes not listed).
- chr19:36,334,453–39,786,291, 169 genes, copy number 7–10 (within-gene range 1–10) (broad region; genes not listed).
- chr21:44,107,373–46,665,124, 123 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
